Somatic mutation profile of tumor specimen 0DWBCC from CCDI case PBCNFY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,116 days).
Specimen 0DWBCC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da90d919-f153-4eb7-b96a-eb8ce287d7d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWBCN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a02658-f47d-4e3c-9c2f-305fdc083b48

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonstop Mutation 1, Nonsense Mutation 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL7 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 75/541 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1241090597, COSV61641451; called by muse, mutect2, varscan2
- NHSL1 | c.3056T>C p.L1019S | Missense Mutation (SNP) | VAF 68/1242 reads (5%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.015); catalogued as rs1203790660; called by muse, mutect2
- TLE1 | c.1012C>G p.R338G | Missense Mutation (SNP) | VAF 55/940 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV64691693; called by muse, mutect2
- DNAH2 | c.12299G>A p.S4100N | Missense Mutation (SNP) | VAF 43/692 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- KIF16B | c.3662A>G p.Y1221C | Missense Mutation (SNP) | VAF 55/923 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC14 | c.1482A>G p.*494Wext*1 | Nonstop Mutation (SNP) | VAF 19/425 reads (4%) | called by muse, mutect2
- MTHFD1 | c.1885-6C>G | Splice Region (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- SLCO3A1 | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STAM | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 45/994 reads (5%) | called by muse, mutect2
- SYCE1 | c.672C>G p.T224= (on ENST00000343131 / NM_001143764.3; = p.T188= on NM_130784.3) | Silent (SNP) | VAF 55/644 reads (9%) | called by muse, mutect2
